Gene-level copy-number profile of tumor specimen TCGA-DX-A6BE-01A from TCGA case TCGA-DX-A6BE, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 77.7 years (28,368 days).
Specimen TCGA-DX-A6BE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.4939b4a9-4608-4d39-bb4f-f6c53e55d9ea.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A6BE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b50c6476-97ed-4375-9694-d73b48ee631e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,394; copy number 2: 56,614; copy number 3: 197; copy number 4: 1; copy number 5: 49; copy number 6: 25; copy number 7: 81; copy number 8: 5; copy number 9: 25; copy number 10: 20; copy number 11: 68; copy number 12: 31; copy number 13: 92; copy number 14: 14; copy number 16: 48; copy number 17: 46; copy number 18: 42; copy number 19: 8; copy number 20: 4; copy number 21: 6; copy number 22: 2; copy number 23: 6; copy number 24: 11; copy number 25: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A6BE-01A-41D-A32H-01): tumor purity 0.36, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 611 genes in 55 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,605,847–60,868,009, 37 genes, copy number 7–18 (within-gene range 6–18): RPS20P5, DAB1-AS1, HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1.
- chr1:62,454,298–63,025,658, 12 genes, copy number 5 (within-gene range 1–5): DOCK7, AL451044.1, ANGPTL3, AL138847.2, AL138847.1, AC103923.1, ATG4C, AC099794.1, AC099794.2, LINC01739, AL162400.3, AL162400.1.
- chr1:67,267,601–68,202,987, 17 genes, copy number 5–7 (within-gene range 2–7): RNU4ATAC4P, DNAJB6P4, IL12RB2, SERBP1, RNU6-387P, LINC01702, RNU6-1031P, AL590559.1, RN7SL392P, HNRNPCP9, GADD45A, GNG12, RNU7-80P, GNG12-AS1, AL157407.1, DIRAS3, ARL5AP3.
- chr1:82,212,413–83,480,024, 5 genes, copy number 5–7: AL157944.1, LINC01362, LINC01361, AC116099.1, LINC01712.
- chr8:150,584–488,512, 16 genes, copy number 7: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2.
- chr8:3,373,353–3,700,628, 3 genes, copy number 10: AC026991.1, AC026991.2, RNA5SP251.
- chr8:15,806,149–16,567,490, 7 genes, copy number 13: PPM1AP1, AC018437.3, AC018437.1, AC018437.2, MSR1, CCT3P1, MRPL49P2.
- chr8:20,655,184–20,950,175, 3 genes, copy number 10 (within-gene range 2–10): AC018541.1, TMEM97P2, AC015468.3.
- chr8:20,953,127–20,995,119, 3 genes, copy number 10: AC015468.1, AC015468.2, LINC02153.
- chr8:32,927,913–33,045,445, 4 genes, copy number 6 (within-gene range 2–6): AC090204.1, MTND1P6, MTND2P32, RANP9.
- chr9:72,007,881–72,299,838, 8 genes, copy number 6: HSPB1P1, C9orf57, AL583829.1, BTF3P4, GDA, AL135924.2, AL135924.1, RNA5SP285.
- chr9:74,935,176–75,147,265, 8 genes, copy number 19: AL158825.1, C9orf40, CARNMT1-AS1, CARNMT1, AL158825.2, AL158825.3, NMRK1, OSTF1.
- chr9:75,401,889–75,724,575, 3 genes, copy number 8–10: AL158073.1, AL353780.1, OTX2P1.
- chr9:76,286,494–76,399,586, 3 genes, copy number 11: RBM22P5, RFK, RPSAP9.
- chr9:81,583,683–81,977,089, 11 genes, copy number 24 (within-gene range 2–24): TLE1, AL591368.1, RNU6-1035P, RNA5SP287, AL158154.1, SPATA31D5P, AL158154.2, SPATA31D4, AL158154.3, SPATA31D3, SPATA31D2P.
- chr9:83,200,940–83,538,546, 6 genes, copy number 7: RN7SKP242, AL137847.3, AL137847.1, FRMD3, AL137847.2, RNU4-29P.
- chr9:85,492,579–86,758,347, 23 genes, copy number 16: STK33P1, AGTPBP1, AL353743.4, AL157882.1, AL353743.2, AL353743.1, PHBP7, AL353743.3, NAA35, GOLM1, AL161447.2, AL161447.1, C9orf153, AL137849.1, RN7SKP264, ISCA1, TUT7, AL353678.1, AL158828.1, RNU2-36P, AL353613.1, LINC02834, AL159996.1.
- chr9:86,948,666–87,708,634, 11 genes, copy number 5–16 (within-gene range 2–16): GAS1RR, AL513318.1, CDC20P1, NFYCP2, LINC02872, AL136367.1, AL353752.1, AL353752.2, DAPK1, AL161787.1, DAPK1-IT1.
- chr9:88,484,852–88,803,716, 5 genes, copy number 11 (within-gene range 2–11): AL353748.1, NXNL2, LINC02843, AL390791.1, MIR4289.
- chr12:45,164,186–45,727,775, 9 genes, copy number 10–17: AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1.
- chr12:46,004,038–46,876,784, 12 genes, copy number 11–13 (within-gene range 2–13): AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1.
- chr12:55,158,847–55,872,602, 49 genes, copy number 5–16: OR9R1P, OR10U1P, OR10A7, OR6C74, OR6C69P, OR6C72P, OR6C6, OR6C5P, OR6C1, OR6C3, OR6C7P, OR6C75, OR6C71P, OR6C66P, OR6C73P, OR6C65, PHC1P1, OR6C76, AC122685.1, OR6C2, OR6C70, OR6C68, OR6C64P, OR6C4, OR2AP1, OR6U2P, OR10P1, AC009779.4, OR10AE3P, PSMB3P1, AC009779.5, METTL7B, ITGA7, AC009779.3, BLOC1S1, RDH5, CD63, AC009779.2, Metazoa_SRP, AC009779.1, GDF11, SARNP, AC023055.1, AC073487.1, ORMDL2, DNAJC14, TMEM198B, MMP19, OLA1P3.
- chr12:57,253,762–58,813,060, 58 genes, copy number 13–18 (within-gene range 2–18): R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388.
- chr12:64,622,509–65,135,273, 18 genes, copy number 6–12: MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3.
- chr12:65,758,020–66,170,072, 13 genes, copy number 9–23: RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4.
- chr12:68,201,349–68,971,570, 28 genes, copy number 25: IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,326,574–70,543,040, 27 genes, copy number 7–12: AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1.
- chr12:71,439,798–71,594,404, 4 genes, copy number 5–8: LGR5, AC090116.1, AC078860.3, AC078860.2.
- chr12:73,648,666–74,402,600, 11 genes, copy number 11–21: AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3.
- chr12:75,020,969–75,390,928, 8 genes, copy number 9–17 (within-gene range 2–17): AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1.
- chr12:75,563,202–76,348,415, 21 genes, copy number 12–23: AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6, RN7SL734P, AC011611.2, AC011611.1, PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5, AC233290.2, AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10.
- chr12:77,021,248–78,359,746, 9 genes, copy number 6–17 (within-gene range 6–37): E2F7, AC079030.1, LINC02464, NAV3, AC073591.1, AC138331.1, AC073571.1, PRXL2AP1, LINC02424.
- chr12:78,793,526–79,452,008, 4 genes, copy number 5 (within-gene range 2–5): AC068993.1, AC068993.2, SYT1, AC090709.1.
- chr14:20,365,667–20,441,268, 4 genes, copy number 11 (within-gene range 2–11): TEP1, RNA5SP382, KLHL33, AL355075.5.
- chr14:21,736,152–22,190,713, 45 genes, copy number 7–13: TRAV4, TRAV5, RPL4P1, TRAV6, TRAV7, TRAV8-1, TRAV9-1, TRAV10, TRAV11, TRAV12-1, TRAV8-2, TRAV8-3, TRAV13-1, TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33.
- chr14:22,202,583–22,304,553, 8 genes, copy number 7: TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39.
- chr14:23,125,295–23,729,757, 32 genes, copy number 11 (within-gene range 2–11): SLC7A8, RNU6-1138P, RNF212B, AL049829.1, RNU6-1046P, HOMEZ, H3P37, PPP1R3E, BCL2L2, BCL2L2-PABPN1, PABPN1, SLC22A17, EFS, AL049829.2, IL25, CMTM5, MYH6, MIR208A, MYH7, AL132855.1, MIR208B, NGDN, ZFHX2-AS1, ZFHX2, AL135999.2, THTPA, AP1G2, AL135999.1, JPH4, AL135999.3, DHRS2, AL160237.1.
- chr14:31,025,106–31,207,804, 4 genes, copy number 10 (within-gene range 2–10): AP4S1, HECTD1, RPL21P5, RNU6-541P.
- chr17:8,172,457–8,270,491, 11 genes, copy number 18 (within-gene range 2–18): TMEM107, SNORD118, AC129492.4, MIR4521, BORCS6, AC129492.6, AC129492.5, AURKB, LINC00324, CTC1, PFAS.
- chr19:9,683,294–10,231,286, 31 genes, copy number 17 (within-gene range 2–17): RPS4XP22, ZNF812P, AC008759.3, AC008759.1, AC008759.2, ZNF846, AC008752.3, UBE2L4, AC008752.1, FBXL12, SNORA70, RPL10P15, UBL5, AC008752.2, PIN1, OLFM2, COL5A3, AC008742.1, RDH8, C3P1, MIR5589, SHFL, AC020931.1, ANGPTL6, PPAN-P2RY11, PPAN, SNORD105, SNORD105B, P2RY11, EIF3G, DNMT1.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
